Gene-level copy-number profile of tumor specimen TCGA-02-0075-01A from TCGA case TCGA-02-0075, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.5 years (23,205 days).
Specimen TCGA-02-0075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ac018a8c-a6e2-4291-a4bf-a330ae9c441e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0075-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef09fb05-501a-4055-922b-7bf82a3b4460

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 25; copy number 2: 6,855; copy number 3: 26,545; copy number 4: 17,941; copy number 5: 5,176; copy number 6: 3,278.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0075-01): tumor purity 0.69, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
